Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-8469, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-8469-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT PELVIC LYMPH NODES, EXCISION –

TWENTY-FOUR BENIGN LYMPH NODES/LYMPH NODE FRAGMENTS (0/24). NO EVIDENCE OF MALIGNANCY.

PART 2: LEFT PELVIC LYMPH NODES, EXCISION –

THIRTY-THREE BENIGN LYMPH NODES/LYMPH NODE FRAGMENTS (0/33). NO EVIDENCE OF MALIGNANCY.

PART 3: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY –

- A. PROSTATIC ADENOCARCINOMA, WITH BOTH ACINAR AND PROSTATIC DUCT DIFFERENTIATION, GLEASON SCORE 4+5=9 WITH A TERTIARY GLEASON PATTERN 3 COMPONENT, EXTENSIVELY INVOLVING BOTH RIGHT AND LEFT LOBES OF THE PROSTATE GLAND AND FOCALLY INVOLVING PERIURETHRAL PROSTATIC DUCTS (SLIDE 3BB). GLEASON PATTERNS 4 AND 5 COMPONENTS COMPRISE APPROXIMATELY 80% OF THE SAMPLED PROSTATE TUMOR VOLUME.
- B. MAXIMAL TUMOR DIAMETER IS 2.5 CM IN A HISTOLOGIC SECTION.
- C. CARCINOMA COMPRISES APPROXIMATELY 50-60% OF THE SAMPLED PROSTATE GLAND VOLUME.
- D. CARCINOMATOUS EXTENSIVE, ESTABLISHED EXTRACAPSULAR EXTENSION IS PRESENT IN THE FOLLOWING LOCATIONS: RIGHT AND LEFT POSTERIOR PROSTATE BASE / PERISEMINAL VESICLE SOFT TISSUE (SLIDES 3A, 3C, 3Y, 3KK), LEFT APEX (SLIDE 3Q), LEFT ANTERIOR MID (SLIDE 3T), LEFT ANTERIOR BASE (SLIDE 3Y), RIGHT POSTERIOR APEX (SLIDE 3W), RIGHT POSTERIOR MID (SLIDE 3X), AND LEFT MID PROSTATE (SLIDE 3GG).
- E. EXTENSIVE CARCINOMATOUS, PERINEURAL AND INTRANEURAL INVASION IDENTIFIED.
- F. FOCAL ANGIOLYMPHATIC TUMOR THROMBUS IS IDENTIFIED (SLIDE 3MM).
- G. CARCINOMA INFILTRATES PERISEMINAL VESICLE SOFT TISSUE AND EXTENDS CLOSE TO BUT DOES NOT INVADE SEMINAL VESICLE PARENCHYMA.
- H. BENIGN DISTAL VASA DEFERENTIA.
- I. CARCINOMA FOCALLY INVOLVES RIGHT DISTAL URETHRAL/APICAL PROSTATIC RESECTION MARGIN AND SOFT TISSUE MARGIN ADJACENT TO ONE SEMINAL VESICLE (SLIDE 3SS). MAXIMAL LINEAR EXTENT OF MARGIN POSITIVITY IS 0.15 CM (SLIDE 3SS). ALL OTHER SURGICAL RESECTION MARGINS ARE BENIGN.
- J. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA.
- K. NON-NEOPLASTIC PROSTATE WITH NODULAR HYPERPLASIA AND ORGANIZING AND ORGANIZED THROMBI IN PERIPROSTATIC BLOOD VESSELS.
- L. TNM PATHOLOGIC STAGE = T3a, N0, Mx.
- M. HISTOLOGIC GRADE: G3-4 (see synoptic).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 16.3
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS Ductal adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	80%
WEIGHT OF PROSTATE:	72.87gm
TUMOR SIZE:	Maximum dimension: 2.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	No
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	Yes
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	Focal tumor involvement at margin
LYMPH NODES EXAMINED:	57
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMx
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated
Comment:	Tertiary Gleason pattern 3 component is present.

Source: NCI Genomic Data Commons file 0a07cefb-5fce-4a74-ace6-4b6408af16a7 (TCGA-EJ-8469.15DB2C5F-2BA9-4FC8-B941-AE57E265C757.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).